Surgical pathology report (de-identified scan), TCGA case TCGA-EA-A5ZD, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Asterand, specimen TCGA-EA-A5ZD-01A (Primary Tumor).

Gross Description: Tumor is located and limited in cervix. It is protruded, with 4x3x2cm in size, soft and white-gray surface.

Microscopic Description: Squamous cell are hyperplastic to replace normal squamous cells and infiltrates in muscle propria. Tumor tissue arranges in the form of group or broad sheets or trabecular of tumor cells connecting each other. The malignant cells have abundant, light eosinophilic cytoplasm. The nuclei are fairly enlarged, variability in size and shape, containing coarse clumped chromatin with prominent nucleoli. Mitotic figures are present. Stroma is invasion of lymphocytes. Endocervical glands are normally seen.

Diagnosis Details: Squamous cell carcinoma, Grade II, infiltrating outer half muscle propria

Comments:

Formatted Path Reports: CERVIX TISSUE CHECKLIST

Specimen type: Hysterectomy

Tumor site: Cervix

Tumor size: 4 x 3 x 2 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Lesion less than 4.0 cm

Lymph nodes: Not specified

Lymphatic invasion: Present

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3
Carcinoma, squamous cell NOS
8070/3
Site: Cervix NOS
C539
JW 4/2/13

Reviewed Initials	JW 3/15/13	

Source: NCI Genomic Data Commons file 3c4b29b2-4478-46cc-bb5a-7b669c40f0d0 (TCGA-EA-A5ZD.4BB00D13-61EA-409C-AB1D-07DE3B949C85.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).